MMRF case MMRF_2228 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/701c3195-7d38-472e-a90d-4af5fc197d96

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 527 days (1.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.2 years (22,361 days); ISS stage: II; Days to last known disease status: 527 days (1.4 years); Days to last follow up: 527 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 406 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 392 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 527.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 1.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 27.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 20.6 g/L; Immunoglobulin A 1.77 g/L; Immunoglobulin M 0.85 g/L; Beta 2 Microglobulin 5.33 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.48 mmol/L; Albumin 37 g/L; Total Protein 7.5 g/dL; Glucose 8.64 mmol/L.
- Day 84 (ECOG 2): M Protein 0.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.7 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 12 ×10⁹/L; Absolute Neutrophil 8.5 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 10.8 mmol/L.
- Day 196: M Protein 1.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.6 g/L; Hemoglobin 6.08 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 361 ×10⁹/L; Creatinine 155 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 9.02 mmol/L.
- Day 280: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 339 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 33 g/L; Total Protein 6.6 g/dL; Glucose 6.44 mmol/L.
- Day 351 (ECOG 2): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.63 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 9.74 mmol/L.

Other clinical attributes
- Day 1: Weight: 147 kg; Height: 190 cm.

Biospecimens (2 samples)
- Sample MMRF_2228_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2228_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
